CPTAC case C208854 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/1a63871a-d1ce-4ecd-904c-99f7814a7c41

Demographics
Sex at birth: male; Age at index: 67 years; Vital status: Dead; Days to death: 253 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Temporal lobe; Tumor grade: G4; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 253 days; Progression or recurrence: yes; Days to recurrence: 193 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: Yes.

Biospecimens (8 samples)
- Samples 1104763, 1104768, 1105226, 1105231, SM-JU33I (5 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1105201, SM-JU32Y (2 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105214: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
